CCDI case PBBUHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/b18fdb70-15e3-4fe7-b1d1-2b4576f42de4

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 0.4 years (129 days).

Biospecimens (3 samples)
- Sample 0DHFL1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHFLT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHFOP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
